Gene-level copy-number profile of tumor specimen TCGA-06-0875-01A from TCGA case TCGA-06-0875, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.1 years (22,312 days).
Specimen TCGA-06-0875-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.a82a098a-b2b7-42e5-85ea-fae69ed349b5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0875-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2cd716e5-30a0-4436-93b5-96ae5f38cdf2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,575; copy number 3: 9,546; copy number 4: 39,069; copy number 5: 405; copy number 6: 204; copy number 8: 2,963; copy number 10: 3; copy number 11: 17; copy number 18: 32; copy number 20: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0875-01A-01D-0384-01): tumor purity 0.74, ploidy 3.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 53 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:57,693,955–58,920,504, 35 genes, copy number 10–18 (within-gene range 2–18): OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3.
- chr12:75,040,077–75,984,015, 18 genes, copy number 11–20 (within-gene range 4–20): KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1, AC011611.6.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
